TCGA case TCGA-ED-A97K — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8778dc9e-a7db-4464-a8af-11addb5e441a

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Combined hepatocellular carcinoma and cholangiocarcinoma: ICD-O-3 morphology code: 8180/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 55.0 years (20,073 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 6 days.
   Pathology details: Additional pathology findings: Inflammation; Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Micro.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 6 days; Disease response: Tumor Free.

Molecular and laboratory tests
- Albumin 8 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.8; Blood test normal range upper: 5.1].
- Platelets 264 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 400].
- Creatinine 4.6 mg/dL [Blood test normal range lower: 4; Blood test normal range upper: 5.8].
- Total Bilirubin 1 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1.3].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 0.9 [Blood test normal range lower: 0.3; Blood test normal range upper: 1.3].
- Alpha Fetoprotein 3 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 20].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 170 cm; BMI: 22.1.
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption; Viral hepatitis serology tests: Hepatitis B Surface Antigen.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ED-A97K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 1,650 mg.
  Slide TCGA-ED-A97K-01A-02-TSB: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ED-A97K-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ED-A97K-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocholangiocarcinoma (Mixed); Definitive surgical procedure: Lobectomy; Hepatic inflammation adj tissue: Mild; New tumor event diagnosis indicator: No.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis B Surface Antigen.
- Follow-up form: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 6 days; disease-specific survival: no event (censored), 6 days; disease-free interval: no event (censored), 6 days; progression-free interval: no event (censored), 6 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ED-A97K-01A-21D-A381-01): tumor purity 0.38, ploidy 3.43, whole-genome doublings 1.
